TCGA case TCGA-HW-7491 — Brain Lower Grade Glioma (TCGA-LGG)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Gliomas; Primary site: Brain; Tissue source site: MSKCC. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/a85fdb41-24c1-420d-8905-ec297f018bd9

Demographics
Sex at birth: male; Race: white; Country of residence at enrollment: United States; Age at index: 35 years; Vital status: Alive.

Diagnoses (2)
1. Oligodendroglioma, NOS (the primary disease): ICD-O-3 morphology code: 9450/3; ICD-10 code: C71.0; Tissue or organ of origin: Cerebrum; Site of resection or biopsy: Nervous system, NOS; Laterality: Right; Classification of tumor: primary; Age at diagnosis: 35.2 years (12,874 days); Year of diagnosis: 2009; Tumor grade: G2; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Days to last follow up: 2,197 days (6.0 years); Sites of involvement: Brain, Frontal lobe; Supratentorial localization: White Matter.
   Pathology details: Consistent pathology review: Yes.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Temozolomide; Days to treatment start: 1,011 days (2.8 years); Treatment outcome: Treatment Ongoing.
   Recorded as not given: adjuvant Radiation Therapy, NOS; Radiation Therapy, NOS to Head, Face or Neck, NOS, prior to diagnosis; Steroid Therapy, preoperative.
2. Diagnosis record without a diagnosis name: Tumor of origin: diagnosis 1 of this record; Age at diagnosis: 41.3 years (15,071 days); Days to diagnosis: 2,197 days (6.0 years); Prior treatment: Yes.
   Recorded as not given: Pharmaceutical Therapy, NOS; Radiation Therapy, NOS.

Follow-up (4 entries)
- Days to follow up: 854 days (2.3 years); Disease response: With Tumor.
- Days to follow up: 1,222 days (3.3 years); Disease response: With Tumor.
- Days to follow up: 2,078 days (5.7 years); Disease response: With Tumor.
- Day 2,197 (post initial treatment): Progression or recurrence: Yes.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-HW-7491-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Longest dimension: 1.1; Intermediate dimension: 0.7; Shortest dimension: 0.5.
  Slide TCGA-HW-7491-01A-01-BS1: Section location: Bottom; Percent tumor cells: 100; Percent tumor nuclei: 80; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 0.
  Slide TCGA-HW-7491-01A-01-TS1: Section location: Top; Percent tumor cells: 100; Percent tumor nuclei: 80; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 0.
- Sample TCGA-HW-7491-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-HW-7491-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Submitted tumor site: Central nervous system; Histologic diagnosis: Oligodendroglioma; History neoadjuvant treatment: No; History ionizing radiation to head: No; Tumor status: With tumor; Tumor site: Supratentorial, Frontal Lobe; History seizures: No; History neoadjuvant steroid treatment: No; Idh1 mutation test indicator: No.
- Follow-up form 1: Lost to follow-up: No; Treatment outcome first course: Progressive Disease; New tumor event diagnosis indicator: No; Tumor status: With tumor; Treatment outcome at TCGA followup: Stable Disease.
- Follow-up form 2: Lost to follow-up: No; Treatment outcome first course: Progressive Disease; New tumor event diagnosis indicator: Yes; Tumor status: With tumor; New tumor event pharmaceutical treatment: No; New tumor event radiation treatment: No.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: no event (censored), 2,078 days; disease-specific survival: no event (censored), 2,078 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 2,197 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-HW-7491-01A-11D-2023-01): tumor purity 0.93, ploidy 1.81, whole-genome doublings 0.
